TCGA case TCGA-WE-A8ZQ — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Norfolk and Norwich Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/77052f40-374e-4dae-bc17-908b52db0f08

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 48 years; Vital status: Alive.

Diagnoses (5)
1. Nodular melanoma (the primary disease): ICD-O-3 morphology code: 8721/3; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: Progression; Age at diagnosis: 52.8 years (19,303 days); Days to diagnosis: 1,479 days (4.0 years); Prior treatment: No; Days to last follow up: 1,923 days (5.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 48.8 years (17,824 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vemurafenib; Days to treatment start: 1,818 days (5.0 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dabrafenib; Days to treatment start: 1,853 days (5.1 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
4. Metastasis of diagnosis 3 (Nodular melanoma), site: Lower limb, NOS. Age at diagnosis: 53.6 years (19,581 days); Days to diagnosis: 1,757 days (4.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 3 (Nodular melanoma), site: Lung, NOS. Age at diagnosis: 53.6 years (19,581 days); Days to diagnosis: 1,757 days (4.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 1,592 days (4.4 years); Disease response: Tumor Free.
- Day 1,757 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lower limb, NOS; Days to progression: 1,757 days (4.8 years).
- Day 1,757 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,757 days (4.8 years).
- Days to follow up: 1,818 days (5.0 years); Disease response: With Tumor.
- Days to follow up: 1,923 days (5.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WE-A8ZQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 290 mg.
  Slide TCGA-WE-A8ZQ-06A-04-TSD: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WE-A8ZQ-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WE-A8ZQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 2.3; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 6; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,923 days; disease-specific survival: no event (censored), 1,923 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,757 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WE-A8ZQ-06A-41D-A371-01): tumor purity 0.94, ploidy 3.28, whole-genome doublings 1.
